Somatic mutation profile of tumor specimen ALCH-ABW4-TTP1-A (aliquot ALCH-ABW4-TTP1-A-1-0-D-A490-36) from ALCHEMIST case ALCH-ABW4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.9 years (23,716 days).
Specimen ALCH-ABW4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fe61729-44a9-47da-a6e0-5987456be76e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABW4-NB1-A (Blood Derived Normal), aliquot ALCH-ABW4-NB1-A-2-0-D-A490-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c120a3cb-ec4b-40fc-b8dc-f57156c8f25b

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Nonsense Mutation 4, Silent 4, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC2 | c.6806G>A p.R2269Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1400010535; called by muse, mutect2, varscan2
- CORO1B | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV58168064; called by muse, mutect2
- NAB1 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs550425927, COSV61608506; called by muse, mutect2, varscan2
- NOTUM | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs923395838, COSV101293812; called by muse, mutect2
- PCDH11Y | c.1859C>G p.T620R (on ENST00000400457 / NM_032973.2; = p.T609R on NM_032971.3) | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT tolerated (0.51); PolyPhen probably damaging (1); catalogued as COSV53088058; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 14/157 reads (9%) | called by muse, mutect2
- CCDC127 | c.710A>T p.Y237F | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CDC14A | c.34T>C p.C12R | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- CELSR1 | c.3648G>C p.Q1216H | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- COQ8B | c.1625A>T p.D542V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- DLD | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2
- GAPVD1 | c.4244C>T p.S1415F (on ENST00000394104; = p.S1424F on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2
- IFRD1 | c.967G>T p.G323* | Nonsense Mutation (SNP) | VAF 48/554 reads (9%) | called by muse, mutect2
- KCTD10 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- MASP1 | c.716A>C p.E239A | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SETD2 | c.5573_5607del p.P1858Hfs*17 | Frame Shift Del (DEL) | VAF 22/232 reads (9%) | called by mutect2, pindel
- SFTPB | c.443_454del p.P148_E151del | In Frame Del (DEL) | VAF 14/164 reads (9%) | called by mutect2, pindel
- TMEM108 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TNFRSF1B | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 24/212 reads (11%) | called by muse, mutect2, varscan2
- ZNF383 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 25/302 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.07); called by muse, mutect2
- CLK2 | c.372C>T p.R124= | Silent (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2
- KRT12 | c.96C>T p.G32= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- TPBG | c.225C>T p.V75= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- ZNF469 | c.4170C>T p.D1390= (on ENST00000437464; = p.D1418= on NM_001367624.2) | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV71258343; called by muse, mutect2, varscan2
